Somatic mutation profile of tumor specimen TCGA-AB-2838-03A (aliquot TCGA-AB-2838-03A-01W-0726-08) from TCGA case TCGA-AB-2838, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,503 days).
Specimen TCGA-AB-2838-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85f8a726-022a-44b5-9d92-15bb51cd4c9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2838-11A (Solid Tissue Normal), aliquot TCGA-AB-2838-11A-01W-0727-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bd3e423-c687-43aa-a8c1-9a93a6ee2eb2

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 456/1429 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO2 | c.2899G>T p.G967C (on ENST00000356134 / NM_001278597.3; = p.G971C on NM_001278596.3) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV59033794; called by muse, mutect2, varscan2
- ARHGEF11 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143441387; called by muse, mutect2, varscan2
- BRINP3 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs772531253, COSV66520441; called by muse, mutect2, varscan2
- BRINP3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs144952455, COSV66521744; called by muse, mutect2, varscan2
- CUL1 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 186/304 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV57390724; called by muse, mutect2, varscan2
- FEZF2 | c.1064A>T p.H355L | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51863748; called by muse, mutect2, varscan2
- GOLGA4 | c.2099G>C p.R700P | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs150129405, COSV100728688; called by muse, mutect2
- GUCY2C | c.1721A>T p.N574I | Missense Mutation (SNP) | VAF 198/510 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53789490, COSV53792987; called by muse, mutect2, varscan2
- KIF2B | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs757160514, COSV52133332; called by muse, mutect2, varscan2
- KLHL18 | c.1495T>C p.S499P | Missense Mutation (SNP) | VAF 255/686 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51747327; called by muse, mutect2, varscan2
- PTPN5 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV62127430; called by muse, mutect2, varscan2
- PYGO2 | c.1067G>C p.R356P | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63757373; called by muse, mutect2, varscan2
- RFC3 | c.810G>A p.R270= | Splice Region (SNP) | VAF 109/324 reads (34%) | catalogued as COSV66296818; called by muse, mutect2, varscan2
- ARMT1 | c.141C>T p.H47= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as rs1299328996, COSV66178398; called by muse, mutect2, varscan2
- OGDHL | c.72C>T p.V24= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV65103665; called by muse, mutect2, varscan2
- PADI2 | c.585C>T p.P195= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as rs746689551, COSV100970998, COSV64945612; called by muse, mutect2, varscan2
- PLXNB1 | c.5457C>T p.D1819= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs200999356; called by muse, mutect2, varscan2
- PDE4A | chr19:10417818 G>T | 5'Flank (SNP) | VAF 7/22 reads (32%) | catalogued as rs758782923, COSV61801511; called by muse, mutect2, varscan2
